CCDI case PBBRLX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ff4c985f-226b-460d-a904-8d5b995fa44e

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.5 years (1,993 days).

Biospecimens (4 samples)
- Sample 0DEYDP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DEYEI, 0DEYFV (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF0DG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
